Somatic mutation profile of tumor specimen BA2579D (aliquot aq-BA2579D) from BEATAML1.0 case 2238, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,694 days).
Specimen BA2579D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e02f38f-0b83-4a39-9a82-36ed1d2ca0bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2895D (Solid Tissue Normal), aliquot aq-BA2895D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bda30c96-4af7-4d93-918a-eef80cc855ac

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.6106C>A p.P2036T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV101418257; called by muse, mutect2
- GABRB3 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54676421; called by muse, mutect2
